Somatic mutation profile of tumor specimen MP2PRT-PAVHMC-TBP1-A (aliquot MP2PRT-PAVHMC-TBP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PAVHMC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,142 days).
Specimen MP2PRT-PAVHMC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eba04452-bd52-4629-889e-8ac4ad579ad0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHMC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHMC-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9afd3885-07d5-4662-b925-37efb887bbe3

The open-access MAF lists 11 somatic variants for this specimen: 11 protein-altering or splice-affecting.
By variant classification: Missense Mutation 10, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 43/258 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1313466, COSV55548621, COSV55708344, COSV56208539; called by muse, mutect2, varscan2
- CACNA1E | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 137/528 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as rs1206135758, COSV62383550; called by muse, mutect2, varscan2
- DRGX | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 160/515 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.223); catalogued as rs371463020, COSV100938308; called by muse, varscan2
- EBF1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs764404398, COSV58189594; called by muse, varscan2
- IGHV1-69 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as rs536685284; called by muse, varscan2
- TMEM131 | c.290+1G>A p.X97_splice | Splice Site (SNP) | VAF 15/96 reads (16%) | catalogued as rs1236392028; called by muse, mutect2, varscan2
- ADGRE5 | c.2101A>G p.T701A (on ENST00000242786 / NM_078481.4; = p.T608A on NM_001784.5) | Missense Mutation (SNP) | VAF 108/565 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 134/510 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCSK1N | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 72/854 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.539); called by muse, mutect2
- ZFHX3 | c.9024G>A p.M3008I | Missense Mutation (SNP) | VAF 119/358 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.164); called by muse, varscan2
- ZNF599 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
